Somatic mutation profile of tumor specimen TARGET-40-PANMIG-01A (aliquot TARGET-40-PANMIG-01A-02D) from TARGET case TARGET-40-PANMIG, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 14.7 years (5,360 days).
Specimen TARGET-40-PANMIG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7d5a10b7-9667-4fe8-8dc6-87aa5c2ee330.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PANMIG-10A (Blood Derived Normal), aliquot TARGET-40-PANMIG-10A-01Y; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/87cb5f72-b0e4-4327-aeb8-45af0ea72e19

The open-access MAF lists 10 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Intron 2, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATRX | c.5787-2A>G p.X1929_splice | Splice Site (SNP) | VAF 16/16 reads (100%) | catalogued as COSV100970140; called by muse, mutect2, varscan2
- MUC4 | c.3406_3453del p.S1136_T1151del | In Frame Del (DEL) | VAF 15/94 reads (16%) | catalogued as rs1553884945; called by pindel, varscan2*
- PCDHA6 | c.73A>G p.K25E | Missense Mutation (SNP) | VAF 2/10 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1554131041; called by muse, mutect2
- PNPLA6 | c.2437A>T p.T813S (on ENST00000414982 / NM_001166111.2; = p.T765S on NM_006702.5) | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.035); catalogued as rs772492685; called by mutect2, varscan2
- ITPRID1 | c.3114G>T p.K1038N | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.027); called by muse, mutect2
- MYH4 | c.4798T>C p.S1600P | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); called by muse, mutect2
- OR2T1 | c.788C>A p.S263Y | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PCDHA6 | c.71G>C p.W24S | Missense Mutation (SNP) | VAF 2/10 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.089); called by muse, mutect2
- MDC1 | c.3013+51_3013+54del | Intron (DEL) | VAF 8/16 reads (50%) | catalogued as rs1244877370; called by mutect2, varscan2
- OR9Q1 | c.-15+53424A>C | Intron (SNP) | VAF 8/15 reads (53%) | called by muse, mutect2, varscan2
